Surgical pathology report (de-identified scan), TCGA case TCGA-DC-5337, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-5337-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

[REDACTED] with rectosigmoid cancer. No neoadjuvant chemoradiation.

Specimens Submitted:

- 1: SP: Rectosigmoid
- 2: SP: Additional node from left colon
- 3: SP: Distal margin
- 4: SP: Proximal margin

DIAGNOSIS:

- 1. SP: Rectosigmoid:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Rectosigmoid

Tumor Size:

Length is 6.0 cm

Width is 4.0 cm

Maximal thickness is 0.4 cm

Tumor Budding:

Extensive

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubulovillous adenoma

Deepest Tumor Invasion:

Submucosa

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

** Continued on next page **

[page 2 of 4]
2. LYMPH NODES, ADDITIONAL, LEFT COLON, EXCISION:
-THREE BENIGN LYMPH NODES (0/3) AND UNREMARKABLE FIBROVASCULAR TISSUE.

3. 4. COLON, DISTAL AND PROXIMAL MARGINS, EXCISION:
-UNREMARKABLE COLONIC MUCOSA.
-NO CARCINOMA SEEN.

_____ D.

Summary of sections:

** Continued on next page **

[page 3 of 4]
2). The specimen is received in formalin, labeled "Additional node from left colon" and consists of a matted fatty and vascular tissue with possible intermixed lymphoid material measuring 4.8 x 3.8 x 2.2 cm and surrounding fatty tissue. The matted fatty possible lymphoid tissue is sectioned and entirely submitted.

Summary of sections:

U - undesignated

3). The specimen is received in formalin, labeled "distal margin" and consists of a ring of pink tan soft tissue measuring 2.3 x 1.5 x 0.8 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

4). The specimen is received in formalin, labeled "proximal margin" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a plastic piece is noted. A ring of pink tan soft tissue is attached measuring 2.5 x 1.8 x 0.7 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Rectosigmoid

Block	Sect.	Site	PCs
2		DM	2
7		LN	14
1		PM	1
1		RM	1
5		T	5
1		TD	1
2		U	2

Part 2: SP: Additional node from left colon

** Continued on next page **

[page 4 of 4]
Block	Sect.	Site	PCs
8		U	8

Part 3: SP: Distal margin

Block	Sect.	Site	PCs
2		U	2

Part 4: SP: Proximal margin

Block	Sect.	Site	PCs
2		U	2

** End of Report **

Source: NCI Genomic Data Commons file c9c772e4-b2e8-434b-b272-8e52faf459c4 (TCGA-DC-5337.E7906259-E1DF-48BE-8B2E-71578F50C68E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).